Gene-level copy-number profile of tumor specimen TCGA-AB-2802-03A from TCGA case TCGA-AB-2802, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.3 years (18,385 days).
Specimen TCGA-AB-2802-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LAML.54b5d850-9e9d-4fdd-a8d9-b46993687013.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AB-2802-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate.
https://portal.gdc.cancer.gov/files/cf446d18-53cf-4232-a55f-59e00f8857fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 204; copy number 1: 9,669; copy number 2: 49,005; copy number 3: 935; copy number 4: 6.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:61,654,194–62,688,386, 23 genes: AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2, PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P, USP1, DOCK7, AL451044.1, ANGPTL3, AL138847.2, AL138847.1.
- chr5:31,532,287–32,444,740, 29 genes: C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579.
- chr5:172,042,079–172,454,525, 6 genes (within-gene range 0–2): STK10, EFCAB9, UBTD2, AC024561.1, KLF3P1, SH3PXD2B.
- chr9:104,629,754–105,239,221, 11 genes: OR13I1P, OR13C1P, OR13D1, OR13D3P, NIPSNAP3A, NIPSNAP3B, ABCA1, AL359182.1, CT70, AL591506.1, RN7SKP191.
- chr11:122,613,444–123,340,714, 26 genes: GLULP3, AP002469.1, UBASH3B, AP002762.3, AP002762.1, AP002762.2, CRTAM, JHY, RNU4-23P, ATP5PBP5, BSX, AP003040.1, RPL34P23, RPS26P43, RPL31P47, HSPA8, SNORD14E, SNORD14D, SNORD14C, AP000926.2, CLMP, AP000926.1, AP001970.1, U8, LINC02727, PHBP17.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,363. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
